Somatic mutation profile of tumor specimen TARGET-10-PARNBN-09A (aliquot TARGET-10-PARNBN-09A-01D) from TARGET case TARGET-10-PARNBN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,674 days).
Specimen TARGET-10-PARNBN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78a4e634-c2df-49b7-b677-3c2a4cc64eef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNBN-10A (Blood Derived Normal), aliquot TARGET-10-PARNBN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e09fbb7-4969-4d19-b497-197455052ddd

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASCL1 | c.707T>C p.F236S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57152040; called by muse, varscan2
- BCL11B | c.1363T>A p.Y455N (on ENST00000357195 / NM_001282237.2; = p.Y384N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61733042, COSV61736973; called by muse, mutect2, varscan2
- DYNC2H1 | c.6812G>A p.G2271D | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV62099204; called by muse, mutect2, varscan2
- RDH5 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57676694; called by muse, mutect2, varscan2
- USP7 | c.1303_1304insGTTCCTTC p.E435Gfs*38 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as COSV61215805; called by mutect2, pindel, varscan2
- AMPD1 | c.1387G>T p.G463C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGB1 | c.6604G>T p.D2202Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLK4 | c.1643C>A p.A548E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- PTPN13 | c.3947C>A p.S1316* (on ENST00000411767 / NM_080683.3; = p.S1297* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- SCRN3 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- SLFN11 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- ASXL3 | c.4530C>T p.S1510= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs566372551; called by muse, varscan2
- RAB41 | c.18C>T p.H6= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as COSV52104163; called by muse, mutect2, varscan2
- WNK4 | c.1644C>T p.P548= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs142230858; called by muse, mutect2, varscan2
- DAAM2 | c.258+98C>A | Intron (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- PRKRIP1 | c.*23C>A | 3'UTR (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100700351; called by muse, mutect2
